Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4368, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4368-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Not specified. Tumor configuration: Ulcerating. Tumor size: 9 x 8 x 2 cm. Histologic type: Adenocarcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Liver Lymph nodes: 8 of 12 positive for metastasis. Margins – Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 22b55d93-e7e2-48e9-822d-acc2089764c5 (TCGA-BR-4368.61AD409F-93B2-41F8-8ACE-A44D1B9A6E47.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).